HCMI case HCM-EXPT-1251-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/fe72b434-4008-4e02-907d-4f32717666bc

Demographics
Sex at birth: female; Days to birth: -26,480 days (72.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.9; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Tumor grade: G3; Esophageal columnar dysplasia degree: Negative/ No Dysplasia; Esophageal columnar metaplasia present: Yes; Gastric esophageal junction involvement: Yes; Goblet cells columnar mucosa present: Yes; Uicc clinical stage: Stage IIIA; Uicc pathologic m: M0; Uicc pathologic n: N1; Uicc pathologic stage: Stage IIIA; Uicc pathologic t: T3; Uicc staging system edition: 7th.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Fluorouracil + Leucovorin + Oxaliplatin; Treatment intent type: Neoadjuvant; Days to treatment start: 90 days.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (1 sample)
- Sample HCM-EXPT-1251-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
